Surgical pathology report (de-identified scan), TCGA case TCGA-DW-7838, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DW-7838-01A (Primary Tumor).

[page 1 of 5]
DIAGNOSIS:

1. Kidney, left, mass, #1 (excision): Renal cell carcinoma, papillary type I.
2. Kidney, left, mass, #2 (excision): Renal cell carcinoma, papillary type I.
3. Kidney, left, mass, #3 (excision): Renal cell carcinoma, papillary type I.
4. Kidney, left, mass, #4 (excision): Renal cell carcinoma, papillary type I.
5. Kidney, left, mass, #5 (excision): Renal cell carcinoma, papillary type I; incipient lesions present.
6. Kidney, left, mass, #6 (excision): Renal cell carcinoma, papillary type I.
7. Kidney, left, mass, #7 (excision): Renal cell carcinoma, papillary type I.
8. Kidney, left, mass, #8 (excision): Renal cell carcinoma, papillary type I.
9. Kidney, left, mass, #9 (excision): Renal cell carcinoma, papillary type I.
10. Kidney, left, mass, #10 (excision): Renal cell carcinoma, papillary type I with spindle and clear cell differentiation.
11. Kidney, left, mass, #11 (excision): Renal cell carcinoma, papillary type I with spindle and clear cell differentiation.
12. Kidney, left, mass, #12 (excision): Renal cell carcinoma, papillary type I.
13. Kidney, left, mass, #13 (excision): Renal cell carcinoma, papillary type I with spindle cell differentiation.
14. Kidney, left, mass, #14 (excision): Renal cell carcinoma, papillary type I.

Patient Identification

[page 2 of 5]
-
-
15. Kidney, left, mass, #15 (excision): Renal cell carcinoma, papillary type I.
16. Kidney, left, mass, #16 (excision): Renal cell carcinoma, papillary type I.
17. Kidney, left, mass, #17 (excision): Renal cell carcinoma, papillary type I; incipient lesions present.
18. Soft tissue, perinephric, left (excision): Fibroadipose tissue.

CLINICAL INFORMATION: Allocate Order to [REDACTED] Brief Clinical History: pt with history of renal cell carcinoma with multiple left renal masses

PROCEDURE: Partial nephrectomy.

SPECIMENS SUBMITTED: 1. KIDNEY, LEFT NEPHRECTOMY, Tumor #1

2. KIDNEY, LEFT NEPHRECTOMY, Tumor #2
3. KIDNEY, LEFT NEPHRECTOMY, Tumor #3
4. KIDNEY, LEFT NEPHRECTOMY, Tumor #4
5. KIDNEY, LEFT NEPHRECTOMY, Tumor #5
6. KIDNEY, LEFT NEPHRECTOMY, Tumor #6
7. KIDNEY, LEFT NEPHRECTOMY, Tumor #7
8. KIDNEY, LEFT NEPHRECTOMY, Tumor #8
9. KIDNEY, LEFT NEPHRECTOMY, Tumor #9
10. KIDNEY, LEFT NEPHRECTOMY, Tumor #10
11. KIDNEY, LEFT NEPHRECTOMY, Tumor #11
12. KIDNEY, LEFT NEPHRECTOMY, Tumor #12
13. KIDNEY, LEFT NEPHRECTOMY, Tumor #13
14. KIDNEY, LEFT NEPHRECTOMY, Tumor #14
15. KIDNEY, LEFT NEPHRECTOMY, Tumor #15
16. KIDNEY, LEFT NEPHRECTOMY, Tumor #16
17. KIDNEY, LEFT NEPHRECTOMY, Tumor #17
18. FAT, Perinephric

GROSS DESCRIPTION: Received are 18 containers labeled with the patient's name, medical record number, and further specified as follows:

1. "Tumor #1". The specimen consists of a yellow-tan nodule measuring 0.8 cm in greatest dimension, is bisected and submitted in toto in a white cassette labeled [REDACTED] for permanent processing.
2. "Tumor #2". The specimen consists of a red/tan soft tissue mass measuring 2.5 x 2.5 x 2 cm. Sectioning reveals a yellow-tan, solid cut surface. Approximately 50% of tissue is procured for the [REDACTED] Laboratory. The specimen received at the [REDACTED] is consistent with the above description. Representative sections are submitted in white cassettes labeled [REDACTED] #2A-2C for permanent processing.

Patient Identification

[REDACTED]

[REDACTED]

[page 3 of 5]
- [REDACTED]
3. "Tumor #3", is a tissue mass measuring 1.5 x 1.2 x 1 cm. Sectioning reveals a yellow-tan, soft cut surface with hemorrhagic foci. 50% is procured for the [REDACTED] Laboratory and the remaining tissue is sent to Surgical Pathology. The specimen received at the [REDACTED] is consistent with the above description, is sectioned and submitted in toto in white cassette labeled [REDACTED] #3A for permanent processing.
4. "Tumor #4". The specimen is a soft tissue fragment measuring 1 x 1 x 1 cm. Sectioning reveals a tan cut surface with a white/tan area in the center. Approximately 50% is procured for the [REDACTED] Laboratory and the remaining tissue is sent to Surgical Pathology. The specimen received at the [REDACTED] is consistent with the above description, is sectioned and submitted in toto in a white cassette labeled [REDACTED] #4A for permanent processing.
5. "Tumor #5". The specimen is a yellow-tan fragment of tissue measuring 1 x 0.5 x 0.3 cm, is collected by filtration, and submitted in toto in a white cassette labeled [REDACTED] #5A for permanent processing.
6. "Tumor #6". The specimen is a yellow-tan nodule measuring 0.3 cm in greatest dimension, is collected by filtration, and submitted in toto in a white cassette labeled [REDACTED]
7. "Tumor #7". The specimen is a yellow-tan fragment of tissue measuring 0.3 cm in greatest dimension, is collected by filtration, and submitted in toto in a white cassette labeled [REDACTED] #7A for permanent processing.
8. "Tumor #8". The specimen is a yellow-tan nodule measuring 0.4 cm in greatest dimension, is collected by filtration, and submitted in toto in an orange cassette labeled [REDACTED] #8A for permanent processing.
9. "Tumor #9". The specimen is a yellow-tan nodule measuring 0.6 cm in greatest dimension and is submitted in toto in a white cassette labeled [REDACTED] #9A for permanent processing.
10. "Tumor #10". The specimen is a corrugated nodule measuring 2 x 1 x 0.8 cm, is sectioned and submitted in toto in a white cassette labeled [REDACTED] #10A for permanent processing.
11. "Tumor #11". The specimen is a fragment of soft tissue measuring 4 x 2.5 x 2.5 cm. Sectioning reveals a yellow-tan cut surface. Approximately 50% is procured for the [REDACTED] Laboratory and the remaining tissue is sent to Surgical Pathology. The specimen received at the Laboratory of Pathology is consistent with the above description. Representative sections are submitted in white cassettes labeled [REDACTED] #11A-#11D for permanent processing.
12. "Tumor #12". The specimen is a fragment of soft tissue measuring 1.3 x 1.2 x 1 cm. Sectioning reveals a tan cut surface with hemorrhagic foci, partially cystic with blood. Approximately 50% is procured for the [REDACTED] and the remaining tissue is sent to Surgical Pathology. The specimen received at the Laboratory of Pathology is consistent with the above description and is submitted in toto in a white cassette labeled [REDACTED] #12A for permanent processing.

Patient Identification

[REDACTED]

[page 4 of 5]
-
13. "Tumor #13". The specimen is a yellow-tan nodule measuring 0.8 cm in diameter. Sectioning reveals a tan smooth cut surface. The specimen is submitted in toto in a white cassette labeled [REDACTED] #13A for permanent processing.
14. "Tumor #14". The specimen is a yellow-tan nodule measuring 0.7 cm in greatest dimension, is bivalved and submitted in toto in a white cassette labeled [REDACTED] #14A for permanent processing.
15. "Tumor #15". The specimen is a yellow-gray nodule measuring 0.7 cm in greatest dimension that appears to be sectioned, is submitted in toto in a white cassette labeled [REDACTED] #15A for permanent processing.
16. "Tumor #16". The specimen is a yellow-tan fragment of tissue measuring 1 x 0.5 x 0.3 cm and is submitted in toto in a white cassette labeled [REDACTED] #16A for permanent processing.
17. "Tumor #17". The specimen is a mass measuring 5.5 x 5 x 4.5 cm. Sectioning reveals a yellow-tan solid cut surface with areas of hemorrhage. Approximately 50% is procured for the [REDACTED] and the remaining tissue is sent to Surgical Pathology. The specimen received at the Laboratory of Pathology is consistent with the above description. Representative sections are submitted in white cassettes labeled [REDACTED] #17A-#17F for permanent processing.
18. "Perinephric fat". The specimen is an irregular fibrofatty fragment of tissue measuring 7.5 x 6.5 x 3 cm. Dissection reveals two areas of apparent fibrosis measuring 3 x 0.5 x 0.5 cm (#1) and 3 x 1 x 0.5 cm (#2). No lymph nodes are identified. Representative sections of fibrofatty tissue are submitted in white cassette labeled [REDACTED] #18A for permanent processing. Area of firmness #1 is submitted in white cassette labeled [REDACTED] #18B-#18H for permanent processing. Area of firmness #2 is submitted in white cassettes labeled [REDACTED] #18I-#18K for permanent processing.

Procurement is carried out by [REDACTED]

[REDACTED]

No consultants

Source: NCI Genomic Data Commons file feb39be6-a5ec-421f-8231-3787298f14ad (TCGA-DW-7838.50A84428-73F9-414B-B79E-4975345B8DE2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).